Surgical pathology report (de-identified scan), TCGA case TCGA-NJ-A4YQ, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Rush University, specimen TCGA-NJ-A4YQ-01A (Primary Tumor).

[page 1 of 10]
Procedure Location:

PATHOLOGY SURGICAL

Results

ICD-O-3

Path: adenocarcinoma, NOS 8140/3
CQCF: adenocarcinoma, w/ mixed subtypes 8255/3
Site: lung, upper lobe C34.1
12/5/16

Entry Date

Component Results

PATHOLOGY RESULT:

Department of Pathology

[page 2 of 10]
Final

Clinical Data Repository* This report may not match the original report
format

FINAL DIAGNOSIS

A. (Lung, left upper lobe; wedge resection): Invasive poorly differentiated
adenocarcinoma (grade 3), measuring 2.2 cm in greatest dimension.

Lymphovascular invasion by tumor is present. Visceral pleura is negative for
malignancy. Stage pT1bN0(PL0). See note.

B. (Lymph node, level 5; biopsy): Fragment of benign lymph node tissue.
Negative for malignancy.

C. (Lymph node, level 10; biopsy): Fragment of benign lymph node tissue.
Negative for malignancy.

D. (Lymph node, level 12; biopsy): Fragments of benign lymph node tissue.
Negative for malignancy.

E. (Lung, left upper lobe; completion lobectomy): Segment of lung tissue
negative for malignancy. Bronchial and vascular margins negative for
malignancy. Three hilar lymph nodes negative for malignancy.

[page 3 of 10]
F. (Lymph node, level 6; biopsy): Fragments of benign lymph node tissue.

Negative for malignancy.

INTRAOPERATIVE CONSULTATION

A. FROZEN: LEFT UPPER LOBEWEDGE: Non-small cell carcinoma, favor adenocarcinoma. (A91, TP, smear)

E. LEFT UPPER LOBE-FROZEN ON BRONCHIAL MARGIN: Bronchial margin negative for malignancy. (E91)

NOTE

A. Immunostains performed on the tumor show the malignant cells are strongly positive for CK7, show weak and focal positivity for TTF-1 and are negative for CK5/6 and P63. This pattern supports the above diagnosis.

[page 4 of 10]
Immunohistochemistry controls are examined and show appropriate reactivity.

Lung Cancer Summary

Specimen type: Wedge resection and completion lobectomy

Tumor location: Left upper lobe

Tumor size: 2.2 cm

Histologic type: Adenocarcinoma

Histologic grade: 3

Status of margins:

Bronchial: Negative

Vascular: Negative

Parenchymal: Negative

Pleural: Negative

Visceral/Parietal pleural invasion: Absent

Lymphatic vascular invasion: Present

Lymph node status: Negative (levels 5, 10, 12, 6)

[page 5 of 10]
Extension into other structures: Absent

Non-neoplastic pathology: NA

TMN stage: pT1bNO(PLO)

GROSS DESCRIPTION

A. The specimen is labeled left upper lobe wedge. Received fresh for frozen section, is a 6.5 x 1.8 x 0.9 cm lung wedge resection specimen with a 7.4 cm staple margin. There is a palpable mass underneath the pleural surface near the center of the specimen. The pleural surface around this area is inked green, and the specimen is serially sectioned to reveal a 2.2 x 1.8 x 1.5 cm somewhat irregular shaped, but well-defined, yellow-tan to grey-tan mass that approaches closest within 4 mm of the stapled margin and approximately 2 mm of the visceral pleural surface. A touch prep and smear are prepared and a representative section of the tumor is submitted for frozen section with the remnant placed in cassette A91. Additional representative sections are submitted as follows: A1 staple margin, A2 and A3 additional sections of tumor with surrounding lung parenchyma, A4 additional section of lung parenchyma.

B. The specimen is labeled level 5L. Received in formalin is a 1.7 x 1.5 x

[page 6 of 10]
0.5 cm segment of black-tan lymphoid tissue. The specimen is bisected and entirely submitted in cassette B1.

C. The specimen is labeled level 10 node. Received in formalin is a 1.8 x 1.0 x 0.4 cm segment of black-tan lymphoid tissue. The entire specimen is submitted in cassette C1.

D. The specimen is labeled level lumbar 12 node. Received in formalin are two fragments of soft black tissue that measures 0.3 x 0.2 x 0.2 cm and 0.2 x 0.2 x 0.2 cm. The entire specimen is wrapped in blue paper and submitted entirely in cassette D1.

E. The specimen is labeled left upper lobe. Received fresh for frozen section, is an 18 x 9 x 2.5 cm lung lobectomy specimen. There is an area of hemorrhage possibly corresponding to the previous wedge site; however, no additional masses or lesions are identified. The bronchial vascular parenchymal margins are stapled. Representative sections are submitted as follows: E91 frozen section, bronchial margin, E1 vascular margin and three possible hilar lymph nodes, E2 parenchymal margin, E3 somewhat hemorrhagic area of lung parenchyma, E4 additional section of lung parenchyma.

F. The specimen is labeled level 6 node. Received in formalin are three fragments of black-tan lymphoid tissue, measuring 1.7 x 1.6 x 0.5 cm in aggregate. The entire specimen is submitted in cassette F1.

[page 7 of 10]
SPECIMEN(S) RECEIVED

A: FROZEN: LEFT UPPER LOBEWEDGE

B: LEVEL #5 NODE

C: LEVEL #10 NODE

D: LEVEL#12 NODE

E: LEFT UPPER LOBE-FROZEN ON BRONCHIAL MARGIN

F: LEVEL 6 NODE

*** The above listed tests (if any) were developed and the performance characteristics determined by _____ These tests have not been cleared or approved for commercial use by the U.S. Food and Drug Administration. The FDA has determined that FDA review is not required for such in-house assays.**

OPERATIVE INFORMATION

DIAGNOSIS: LUNG NODULE; PROCEDURE: BRONCHOSCOPY FLEXIBLE FIBEROPTIC, THORACOSCOPY VIDEO ASSISTED

INTRADEPARTMENT CONSULTATION PATHOLOGIST: QA COMMITTEE

ICD-9(s): -

[page 8 of 10]
The attending pathologist was physically present when this specimen was diagnosed, and actively participated in all key decisions.

Lab and Collection

PATHOLOGY SURGICAL

Lab and Collection Information

PATHOLOGY SURGICAL

Pathology

[page 9 of 10]
Procedure Location:

Dx discrepancy Form attached 10/6/12

Immunohistochemistry Discrepancy	☒	☐
Immunohistochemistry Discrepancy	☐	☒
Immunohistochemistry Primary Tumor	☐	☒

[page 10 of 10]
TCGA Pathologic Diagnosis Discrepancy Form

V1.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____
Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Invasive Poorly Differentiated Adenocarcinoma Grade 3.	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	mixed: acinar, solid.	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Path report does not subtype	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 8c0d8c42-5e6d-4372-ab01-c4c66aad3ebf (TCGA-NJ-A4YQ.232A989B-38EA-4BAC-8B08-075913ADA7EF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).